Gene-level copy-number profile of tumor specimen ALCH-ADP3-TTP1-A from ALCHEMIST case ALCH-ADP3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.5 years (27,942 days).
Specimen ALCH-ADP3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ddf00b8d-8b71-4fe2-bf70-2f7131d54e4b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADP3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/3b2ab438-d07f-470c-b802-2cbaf3b1580c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 1,650; copy number 2: 56,199; copy number 3: 345; copy number 4: 50; copy number 5: 45; copy number 6: 29; copy number 7: 12; copy number 8: 11.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,551–91,105, 1 gene (within-gene range 0–2): AL627309.3.
- chr2:2,638,178–2,696,285, 1 gene: AC018685.2.
- chr2:44,921,077–44,941,873, 10 genes: LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1.
- chr3:12,733,528–12,769,457, 1 gene: TMEM40.
- chr3:48,636,463–48,686,364, 5 genes (within-gene range 0–2): CELSR3, MIR4793, LINC02585, AC141002.1, NCKIPSD.
- chr7:1,542,235–1,560,821, 1 gene (within-gene range 0–2): TMEM184A.
- chr10:117,542,445–117,549,546, 1 gene (within-gene range 0–2): EMX2.
- chr10:133,344,643–133,350,726, 2 genes (within-gene range 0–1): BANF1P2, AL360181.1.
- chr11:67,662,160–67,683,058, 2 genes: ALDH3B2, RPL37P2.
- chr11:69,641,156–69,654,474, 1 gene (within-gene range 0–1): CCND1.
- chr12:49,539,030–49,558,337, 1 gene (within-gene range 0–2): KCNH3.
- chr15:25,199,448–25,241,827, 24 genes (within-gene range 0–2): SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39.
- chr19:663,482–669,500, 1 gene: AC004156.1.
- chr20:62,774,121–62,776,996, 1 gene: LINC00659.
- chr22:19,045,256–19,045,367, 1 gene (within-gene range 0–1): Y_RNA.
- chr22:19,756,703–19,783,593, 1 gene (within-gene range 0–2): TBX1.
- chr22:29,711,820–29,731,833, 2 genes (within-gene range 0–2): AC004882.2, CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 97 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,083,499–169,869,935, 17 genes, copy number 6: MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31.
- chr5:121,575,848–122,311,673, 11 genes, copy number 6 (within-gene range 2–6): RPL23AP44, AC106806.1, AC106806.2, FTMT, SRFBP1, LOX, AC010255.1, ZNF474, AC010255.2, ZNF474-AS1, AC113349.2.
- chr8:113,600,310–114,791,929, 5 genes, copy number 5: AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2.
- chr8:117,794,490–118,622,112, 3 genes, copy number 5 (within-gene range 4–5): EXT1, SAMD12, AC023590.1.
- chr8:120,380,761–120,813,359, 6 genes, copy number 5: MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2.
- chr10:120,608,580–121,598,458, 11 genes, copy number 8: AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2.
- chr10:129,768,844–132,976,354, 42 genes, copy number 5–7: AL157832.1, EBF3, AL354950.2, MIR4297, AL354950.1, AL354950.3, C10orf143, AL139123.1, CTAGE7P, PPIAP32, GLRX3, LINC02646, AL157712.1, Y_RNA, MIR378C, TCERG1L, TCERG1L-AS1, LINC01164, AL450307.1, AL607033.1, PPP2R2D, BNIP3, AL162274.2, AL162274.1, AL162274.3, JAKMIP3, AL512622.1, DPYSL4, STK32C, LRRC27, PWWP2B, AL451069.2, AL451069.3, LINC02870, AL451069.1, LINC01165, INPP5A, NKX6-2, CFAP46, LINC01166, LINC01167, LINC01168.
- chr10:133,144,612–133,226,412, 2 genes, copy number 5–6: RPL5P28, KNDC1.

Autosomal genes at a single copy (total copy number 1): 1,650. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
